Surgical pathology report (de-identified scan), TCGA case TCGA-DF-A2KZ, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Ontario Institute for Cancer Research, specimen TCGA-DF-A2KZ-01A (Primary Tumor).

Sample Type TUMOUR

Sample Preparation

Fresh Frozen

Site of Primary (Event)

Uterine

Site of Tissue

endometrial mass

Year of Sample Collection

Age at Sample Collection (yrs)

Sample Comments

Days to Procedure Date

0

Days to Diagnosis

12

Type of Procedure

Surgical resection

Site of Primary (Histology)

Endometrium

Bilateral Disease

UNK

Tumour Size (cm)

4.2000000000000002

Histology

Endometrioid adenocarcinoma, NOS & Endometrioid with

squamous differentiation

Grade/Differentiation

III

Pathological T

T1b

Pathological N

NX

Number of Nodes Sampled

Number of Nodes Positive

99999

Clinical M

M0

Histology Comments

Histology: Endometrioid adenocarcinoma with up to 50%

squamous/transitional differentiation (by immunohistochemistry).

ICD-0-3

adenocarcinoma, endometrioid, NOS 8380/3

Site: endometrium C54.1

lw 11/4/11

Source: NCI Genomic Data Commons file bcec02c4-530f-4e72-838e-bab857b684d4 (TCGA-DF-A2KZ.D69C73D1-1CEB-4AF5-AAF2-8E707EF4CA38.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).